Somatic mutation profile of tumor specimen TARGET-10-PATSIY-09A (aliquot TARGET-10-PATSIY-09A-01D) from TARGET case TARGET-10-PATSIY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.3 years (3,404 days).
Specimen TARGET-10-PATSIY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 900b545d-5e82-4e1d-bd12-142227c6d4f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATSIY-10A (Blood Derived Normal), aliquot TARGET-10-PATSIY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21742fcb-e0ec-4411-980e-86affa3118b8

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 3, Frame Shift Ins 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 23/68 reads (34%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARID1A | c.4379G>A p.G1460D | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV100252621, COSV61389619; called by muse, mutect2, varscan2
- CEMIP2 | c.3047C>T p.P1016L | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs375145196; called by muse, mutect2
- COL22A1 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs199956548; called by muse, mutect2, varscan2
- DDX39A | c.865-2A>G p.X289_splice | Splice Site (SNP) | VAF 48/93 reads (52%) | catalogued as COSV54393490; called by muse, mutect2, varscan2
- DUS1L | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57651520; called by muse, mutect2, varscan2
- GGPS1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs764662240, COSV51397894; called by muse, mutect2, varscan2
- JAK3 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768942227, COSV71685722, COSV71685923; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- TACR3 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as rs1044531754, COSV59201178; called by muse, mutect2, varscan2
- AP3D1 | c.2328C>T p.I776= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs370785097; called by muse, mutect2, varscan2
- GSS | c.399C>T p.S133= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs181055807; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR10H2 | c.97C>T p.L33= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV100008908, COSV59946963; called by muse, mutect2
- OR13G1 | c.162G>A p.T54= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs767970219, COSV62943288, COSV62943347; called by muse, mutect2, varscan2
- PDCD6 | c.447C>T p.D149= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs779736494; called by muse, mutect2
- KCNK16 | c.802+10_802+11insGGACTTCGACCCTTC | Intron (INS) | VAF 8/20 reads (40%) | catalogued as COSV64679514; called by mutect2, varscan2
- MIF4GD | chr17:75272503 C>T | 5'Flank (SNP) | VAF 31/56 reads (55%) | catalogued as rs1169453130; called by muse, mutect2, varscan2
- MST1 | c.1876+32C>T | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- SLC17A6 | c.340-170T>C | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
